MMRF case MMRF_1974 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/c9d10f0c-9e61-41c5-8a86-340f8411bec6

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 60 years; Vital status: Dead; Days to death: 892 days (2.4 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 60.3 years (22,028 days); ISS stage: III; Days to last known disease status: 892 days (2.4 years); Days to last follow up: 892 days (2.4 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 96 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 22 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 4 days; Days to treatment end: 96 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 23 days; Days to treatment end: 96 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 103 days; Days to treatment end: 104 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 106 days; Days to treatment end: 106 days.
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 188 days; Days to treatment end: 363 days.
   Treatment given: Therapeutic agents: Dexamethasone + Other + Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 371 days (1.0 years); Days to treatment end: 398 days (1.1 years).
   Treatment given: Therapeutic agents: Bendamustine + Prednisone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 408 days (1.1 years); Days to treatment end: 419 days (1.1 years).
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: Second line of therapy; Days to treatment start: 429 days (1.2 years); Days to treatment end: 545 days (1.5 years).
   Treatment given: Therapeutic agents: Daratumumab; Regimen or line of therapy: Second line of therapy; Days to treatment start: 573 days (1.6 years); Days to treatment end: 713 days (2.0 years).
   Treatment given: Therapeutic agents: Dexamethasone + Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 573 days (1.6 years); Days to treatment end: 636 days (1.7 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 671 days (1.8 years); Days to treatment end: 713 days (2.0 years).
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: Third line of therapy; Days to treatment start: 721 days (2.0 years); Days to treatment end: 842 days (2.3 years).
   Treatment given: Therapeutic agents: Dexamethasone + Other + Pomalidomide; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 863 days (2.4 years); Days to treatment end: 892 days (2.4 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 892.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0: M Protein 1.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 193 mg/dL; Beta 2 Microglobulin 13.6 µg/mL; Lactate Dehydrogenase 3.17 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 287 ×10⁹/L; Creatinine 669 µmol/L; Blood Urea Nitrogen 22.8 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 8.3 g/dL; Glucose 5.12 mmol/L.
- Day 121 (ECOG 1): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.52 mg/dL; Immunoglobulin G 11.6 g/L; Immunoglobulin A 0.52 g/L; Immunoglobulin M 0.509 g/L; Lactate Dehydrogenase 3.28 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 90 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 1.07 mmol/L; Calcium 2 mmol/L; Albumin 34 g/L; Total Protein 5.6 g/dL; Glucose 5.94 mmol/L.
- Day 188 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.3 mg/dL; Immunoglobulin G 10.3 g/L; Immunoglobulin A 0.968 g/L; Immunoglobulin M 0.393 g/L; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.4 mmol/L; Albumin 39 g/L; Total Protein 6.6 g/dL; Glucose 3.91 mmol/L.
- Day 272 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.6 mg/dL; Immunoglobulin G 11.1 g/L; Immunoglobulin A 0.874 g/L; Immunoglobulin M 0.69 g/L; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 6.3 g/dL; Glucose 5.01 mmol/L.
- Day 384 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 38.1 mg/dL; Immunoglobulin G 7.33 g/L; Immunoglobulin A 0.351 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 1.97 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 95 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.38 mmol/L; Albumin 39 g/L; Total Protein 6.8 g/dL; Glucose 9.57 mmol/L.
- Day 475 (ECOG 2): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.7 mg/dL; Immunoglobulin G 8.44 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 3.55 µkat/L; Hemoglobin 5.39 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 92 ×10⁹/L; Creatinine 131 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.35 mmol/L; Albumin 36 g/L; Total Protein 6.4 g/dL; Glucose 7.65 mmol/L.
- Day 552 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.2 mg/dL; Immunoglobulin G 6.83 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.02 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 2 ×10⁹/L; Absolute Neutrophil 1.26 ×10⁹/L; Platelets 30 ×10⁹/L; Creatinine 104 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 6 g/dL; Glucose 6.49 mmol/L.
- Day 636 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.6 mg/dL; Immunoglobulin G 5.01 g/L; Immunoglobulin A 0.46 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.03 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 0.6 ×10⁹/L; Platelets 172 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.4 mmol/L; Albumin 40 g/L; Total Protein 6 g/dL; Glucose 6.6 mmol/L.
- Day 730 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 21.7 mg/dL; Immunoglobulin G 5.39 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 1.73 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 0.5 ×10⁹/L; Absolute Neutrophil 0 ×10⁹/L; Platelets 58 ×10⁹/L; Creatinine 120 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 6.1 g/dL; Glucose 6.6 mmol/L.
- Day 807 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.5 mg/dL; Immunoglobulin G 3 g/L; Immunoglobulin A 0.5 g/L; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 36 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.4 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 5.5 mmol/L.
- Day 877 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.3 mg/dL; Immunoglobulin G 7.6 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 5.21 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 52 ×10⁹/L; Creatinine 138 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.35 mmol/L; Albumin 34 g/L; Total Protein 5.7 g/dL; Glucose 7.54 mmol/L.

Other clinical attributes
- Day 0: Weight: 90 kg; Height: 176 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1974_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_1974_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
